Somatic mutation profile of tumor specimen TCGA-06-0879-01A (aliquot TCGA-06-0879-01A-01W-0424-08) from TCGA case TCGA-06-0879, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.4 years (19,154 days).
Specimen TCGA-06-0879-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85abb305-6fae-451b-9b83-2e982e7da67e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0879-10A (Blood Derived Normal), aliquot TCGA-06-0879-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2d1c09e-d1f2-4b33-818e-834176663a19

The open-access MAF lists 80 somatic variants for this specimen: 57 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 20, Frame Shift Ins 15, RNA 3, Nonsense Mutation 3, Splice Region 2, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL5A1 | c.2988dup p.G997Rfs*17 | Frame Shift Ins (INS) | VAF 8/51 reads (16%) | catalogued as rs764693725; ClinVar: pathogenic; called by mutect2, varscan2
- CPAMD8 | c.2352dup p.R785Qfs*23 (on ENST00000651564; = p.R738Qfs*23 on NM_015692.5) | Frame Shift Ins (INS) | VAF 20/157 reads (13%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, varscan2
- EGFR | c.2311_2319dup p.N771_H773dup | In Frame Ins (INS) | VAF 43/233 reads (18%) | hotspot (GDC flag); catalogued as rs397517115, COSV51766549, COSV51779915, COSV51787954, COSV51807227, COSV51814184, COSV51816337, COSV51859791; ClinVar: drug response; called by mutect2, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 52/313 reads (17%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- NEUROD1 | c.616dup p.H206Pfs*38 | Frame Shift Ins (INS) | VAF 14/104 reads (13%) | catalogued as rs387906384; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1365_1379del p.L455_G460delinsF | In Frame Del (DEL) | VAF 58/324 reads (18%) | hotspot (GDC flag); called by pindel, varscan2
- AADACL2 | c.998C>T p.T333I | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62930551; called by muse, mutect2, varscan2
- ADCY5 | c.3750G>T p.M1250I | Missense Mutation (SNP) | VAF 38/572 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV59199771; called by muse, mutect2
- AFAP1L1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370079883; called by muse, mutect2, varscan2
- AFF2 | c.3884G>A p.R1295H | Missense Mutation (SNP) | VAF 47/55 reads (85%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs782318095, COSV53980006; called by muse, mutect2, varscan2
- AOC1 | c.2146G>A p.V716M | Missense Mutation (SNP) | VAF 151/483 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs199683372; called by muse, mutect2, varscan2
- AQR | c.3352T>C p.S1118P | Missense Mutation (SNP) | VAF 289/962 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV50033137; called by muse, mutect2, varscan2
- ATP2C1 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.074); catalogued as COSV60756666; called by muse, mutect2, varscan2
- B3GALT5 | c.717T>G p.I239M | Missense Mutation (SNP) | VAF 1002/2356 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV58198850; called by muse, varscan2
- BRDT | c.2819C>A p.T940K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV62864789, COSV62865101; called by muse, mutect2, varscan2
- CAND1 | c.552G>T p.L184F | Missense Mutation (SNP) | VAF 95/259 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV73338593; called by muse, varscan2
- CCDC81 | c.1291A>G p.S431G (on ENST00000445632 / NM_001156474.2; = p.S341G on NM_021827.4) | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV53578561; called by muse, mutect2
- CCDC9B | c.609dup p.T204Hfs*56 | Frame Shift Ins (INS) | VAF 74/631 reads (12%) | catalogued as rs772754432; called by mutect2, varscan2
- CTIF | c.245dup p.Q83Tfs*78 | Frame Shift Ins (INS) | VAF 13/82 reads (16%) | catalogued as rs779060416; called by mutect2, varscan2
- ELAVL1 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 96/349 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV60966642; called by muse, mutect2, varscan2
- EPHX4 | c.515dup p.M173Hfs*12 | Frame Shift Ins (INS) | VAF 94/878 reads (11%) | catalogued as rs765115164; called by mutect2, varscan2
- FAM151A | c.351dup p.T118Hfs*5 | Frame Shift Ins (INS) | VAF 52/440 reads (12%) | catalogued as rs749953492; called by mutect2, varscan2
- FBN2 | c.1396G>A p.G466S | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.394); catalogued as COSV52514596; called by muse, mutect2, varscan2
- GALNT2 | c.163G>C p.D55H | Missense Mutation (SNP) | VAF 130/393 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV64194948; called by muse, mutect2, varscan2
- GLI1 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 105/413 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57362262, COSV99954859; called by muse, mutect2, varscan2
- HLA-DPB1 | c.31dup p.R11Pfs*38 | Frame Shift Ins (INS) | VAF 4/25 reads (16%) | catalogued as rs1048293876; called by pindel, varscan2
- HR | c.3172C>T p.R1058W | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748200419, COSV57191265; called by mutect2, varscan2
- HSP90AB1 | c.1606G>A p.V536I | Missense Mutation (SNP) | VAF 34/1203 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.237); catalogued as rs1188033687; called by muse, mutect2
- ITPR1 | c.2693G>A p.C898Y (on ENST00000354582; = p.C883Y on NM_002222.7) | Missense Mutation (SNP) | VAF 66/239 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56982474; called by muse, mutect2, varscan2
- KEL | c.1199C>A p.P400H | Missense Mutation (SNP) | VAF 68/265 reads (26%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.911); catalogued as rs767483672, COSV62335112; called by muse, mutect2, varscan2
- LGALS8 | c.508A>G p.I170V | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as rs775638029, COSV53024728; called by muse, mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 32/207 reads (15%) | catalogued as rs757410385; called by mutect2, varscan2
- MGAT4C | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs566418071, COSV59832100, COSV59837748; called by muse, mutect2, varscan2
- MINAR1 | c.1574T>C p.L525P | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59583175; called by muse, mutect2, varscan2
- MTUS2 | c.1987G>T p.V663F | Missense Mutation (SNP) | VAF 129/301 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV70916903; called by muse, mutect2, varscan2
- MYH3 | c.249dup p.K84Qfs*16 | Frame Shift Ins (INS) | VAF 34/214 reads (16%) | catalogued as rs761123152; called by mutect2, varscan2
- NCF2 | c.609G>A p.T203= | Splice Region (SNP) | VAF 147/393 reads (37%) | catalogued as rs147657171, COSV62316343; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NT5C1B | c.1200C>T p.Y400= (on ENST00000359846 / NM_001199086.2; = p.Y340= on NM_033253.4) | Splice Region (SNP) | VAF 35/652 reads (5%) | catalogued as rs148193506; called by muse, mutect2
- OSBPL6 | c.2282G>A p.C761Y | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51918464, COSV51930980; called by muse, mutect2, varscan2
- PCDHB13 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 52/327 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.975); catalogued as rs782053306, COSV53394300; called by muse, varscan2
- PPP4R4 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 230/709 reads (32%) | catalogued as rs1566680153, COSV58552370; called by muse, mutect2, varscan2
- SCN1A | c.5914A>T p.K1972* (on ENST00000303395 / NM_001202435.3; = p.K1961* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as rs1553519734, COSV57670774; called by muse, mutect2, varscan2
- SLC10A6 | c.326dup p.T110Hfs*4 | Frame Shift Ins (INS) | VAF 7/46 reads (15%) | catalogued as rs753933531; called by mutect2, pindel, varscan2
- SLC6A18 | c.634A>C p.T212P | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777600288; called by muse, mutect2
- SLC6A6 | c.975C>A p.D325E | Missense Mutation (SNP) | VAF 245/785 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62649853; called by muse, mutect2, varscan2
- TMEM200A | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as rs140251464; called by muse, mutect2, varscan2
- TPTE | c.1574G>T p.R525I (on ENST00000618007 / NM_199261.4; = p.R507I on NM_199259.4) | Missense Mutation (SNP) | VAF 168/1264 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs376317057; called by muse, mutect2, varscan2
- TTN | c.8784G>T p.K2928N (on ENST00000591111; = p.K2882N on NM_003319.4) | Missense Mutation (SNP) | VAF 462/1109 reads (42%) | PolyPhen possibly damaging (0.743); catalogued as COSV60152966; called by muse, mutect2, varscan2
- VILL | c.1438dup p.H480Pfs*38 | Frame Shift Ins (INS) | VAF 8/71 reads (11%) | catalogued as rs753585188; called by mutect2, varscan2
- ZSWIM2 | c.1784G>C p.S595T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV54575573; called by muse, mutect2, varscan2
- AMIGO2 | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLIP2 | c.42dup p.K15Efs*23 | Frame Shift Ins (INS) | VAF 4/35 reads (11%) | called by pindel, varscan2
- NEDD9 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 99/602 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- PCDHB5 | c.214A>T p.K72* | Nonsense Mutation (SNP) | VAF 55/463 reads (12%) | called by mutect2, varscan2
- RNF213 | c.6775G>T p.A2259S | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SPEM2 | c.1361dup p.N455Qfs*65 | Frame Shift Ins (INS) | VAF 2/23 reads (9%) | called by pindel, varscan2
- VPS13D | c.1115A>C p.E372A | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.149); called by mutect2, varscan2
- ARL11 | c.369G>A p.K123= | Silent (SNP) | VAF 47/118 reads (40%) | catalogued as COSV56291272; called by muse, mutect2, varscan2
- CASR | c.189T>C p.Y63= | Silent (SNP) | VAF 8/98 reads (8%) | called by mutect2, varscan2
- CFAP54 | c.6342A>G p.R2114= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV61572943; called by muse, mutect2, varscan2
- CHRNG | c.315C>T p.T105= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV51322717; called by muse, mutect2, varscan2
- COL11A1 | c.5127T>C p.N1709= | Silent (SNP) | VAF 70/442 reads (16%) | catalogued as COSV100615913, COSV62187637; called by muse, mutect2, varscan2
- DCLK1 | c.693G>A p.V231= | Silent (SNP) | VAF 54/395 reads (14%) | catalogued as COSV99710855; called by muse, mutect2, varscan2
- DOCK5 | c.3249C>T p.I1083= | Silent (SNP) | VAF 279/750 reads (37%) | catalogued as rs780661201, COSV52402395; called by muse, mutect2, varscan2
- ESRP2 | c.687G>A p.K229= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs758830514; called by muse, varscan2
- FLG | c.4239C>T p.H1413= | Silent (SNP) | VAF 104/256 reads (41%) | catalogued as rs147032729; called by muse, mutect2, varscan2
- GTSE1 | c.855G>A p.P285= | Silent (SNP) | VAF 72/245 reads (29%) | catalogued as rs749506319, COSV71889093; called by muse, mutect2, varscan2
- MDN1 | c.12498C>T p.S4166= | Silent (SNP) | VAF 53/176 reads (30%) | catalogued as rs116003199; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2667G>A p.E889= | Silent (SNP) | VAF 11/233 reads (5%) | called by muse, mutect2
- PCDHB3 | c.1710G>A p.A570= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV50570519; called by muse, varscan2
- PPP1R12C | c.420G>A p.V140= | Silent (SNP) | VAF 35/144 reads (24%) | catalogued as COSV54737452; called by muse, mutect2, varscan2
- PREX1 | c.984G>A p.R328= | Silent (SNP) | VAF 35/122 reads (29%) | catalogued as COSV64253485; called by mutect2, varscan2
- RIMBP2 | c.1149G>A p.T383= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs149109982; called by muse, mutect2, varscan2
- SLC6A17 | c.1857A>G p.A619= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV58993322; called by muse, mutect2, varscan2
- SORCS3 | c.1242C>T p.Y414= | Silent (SNP) | VAF 618/1031 reads (60%) | catalogued as rs531557060, COSV63810874; called by muse, mutect2, varscan2
- TMEM106B | c.420T>G p.R140= | Silent (SNP) | VAF 136/910 reads (15%) | catalogued as rs140753733; called by muse, mutect2
- ZNF646 | c.1311A>G p.S437= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs773726478; called by mutect2, varscan2
- ARPP19P2 | n.155G>A | RNA (SNP) | VAF 26/55 reads (47%) | catalogued as rs754124555; called by muse, mutect2, varscan2
- MIR509-2 | n.29_30delinsT | RNA (DEL) | VAF 16/48 reads (33%) | called by pindel, varscan2*
- MIR509-3 | n.19C>T | RNA (SNP) | VAF 58/141 reads (41%) | catalogued as rs782329671; called by muse, mutect2, varscan2
